Somatic mutation profile of tumor specimen TCGA-Q1-A6DV-01A (aliquot TCGA-Q1-A6DV-01A-11D-A32I-09) from TCGA case TCGA-Q1-A6DV, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Endocervix; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 36.0 years (13,166 days).
Specimen TCGA-Q1-A6DV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 106d1de0-e8d5-482b-b862-f1d494469c12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Q1-A6DV-10A (Blood Derived Normal), aliquot TCGA-Q1-A6DV-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1ff8da0-4f0b-4a3a-ace1-9e463232725f

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 9, Frame Shift Del 2, Intron 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 12/54 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABR | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.036); catalogued as rs573239507, COSV56843924; called by muse, mutect2, varscan2
- ANKFN1 | c.1216+2T>C p.X406_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | catalogued as COSV59460732; called by muse, mutect2
- ARHGAP35 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs769146124, COSV68335897; called by muse, mutect2, varscan2
- BRD7 | c.1185A>C p.K395N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV67160174; called by muse, mutect2, varscan2
- CLINT1 | c.932C>G p.S311C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.533); catalogued as COSV51629274; called by muse, mutect2, varscan2
- EVX2 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV57964109; called by muse, mutect2, varscan2
- MCM5 | c.2170C>T p.R724C | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV53348394; called by muse, mutect2, varscan2
- MED12 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61334558; called by muse, mutect2, varscan2
- SCN4A | c.1318A>G p.N440D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71129263; called by muse, mutect2, varscan2
- STAB1 | c.4961G>A p.R1654Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as rs779957209, COSV58743533; called by muse, mutect2, varscan2
- TAF4 | c.1777G>A p.V593M | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53334024, COSV53343588; called by muse, mutect2, varscan2
- TBXT | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.487); catalogued as rs767098205, COSV51615976; called by muse, mutect2, varscan2
- TRH | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100234833, COSV57015759; called by muse, mutect2, varscan2
- USP43 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs747323152, COSV53305868; called by muse, mutect2, varscan2
- ZNF479 | c.858C>A p.N286K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV58643939; called by muse, mutect2, varscan2
- ARHGAP35 | c.1333_1334del p.F445Hfs*12 | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | called by mutect2, pindel, varscan2
- KANSL3 | c.1965C>A p.D655E (on ENST00000666923 / NM_001349262.2; = p.D629E on NM_001115016.3) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); called by muse, mutect2
- KMT2C | c.3513_3514del p.T1173Pfs*8 | Frame Shift Del (DEL) | VAF 35/109 reads (32%) | called by mutect2, pindel, varscan2
- C16orf86 | c.72G>A p.T24= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV54677819; called by muse, mutect2, varscan2
- DLC1 | c.3843G>A p.K1281= (on ENST00000276297 / NM_001348081.2; = p.K844= on NM_006094.5) | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs1345569368, COSV52329208; called by muse, mutect2, varscan2
- FN1 | c.6726T>C p.H2242= (on ENST00000359671 / NM_001365524.2; = p.H2211= on NM_002026.4) | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV100115517; called by muse, mutect2
- HHIPL2 | c.372G>A p.T124= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV58566633; called by muse, mutect2, varscan2
- ITGAE | c.1647C>T p.Y549= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as rs1423573802, COSV54000190; called by muse, mutect2, varscan2
- MAGEB2 | c.207C>T p.A69= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as rs370067105, COSV66781918; called by muse, mutect2, varscan2
- MYH6 | c.2190G>A p.V730= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV62454769; called by muse, mutect2, varscan2
- NLRP5 | c.1161G>A p.P387= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs753433376, COSV66765416; called by muse, mutect2, varscan2
- SASH3 | c.573C>T p.H191= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs1432141495, COSV63556752; called by muse, mutect2, varscan2
- MAGI3 | c.3329-656G>A | Intron (SNP) | VAF 24/50 reads (48%) | catalogued as rs141671759; called by muse, mutect2, varscan2
